Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A280, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A280-01A (Primary Tumor).

1 (First Tumor)

Tumor Site:	Ascending Colon		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	.8		
Pathologist Comment:	serrated adenoma		

1CD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: ascending colon C18.2

hw 5/3/11

UUID: EDE93B1A-2535-4D4B-9995-DD050CABASD7

Source: NCI Genomic Data Commons file dca0da49-23c8-4c3a-ba06-4eaa82d6259a (TCGA-DM-A280.EDE93B1A-2535-4D4B-9995-DD050CA8A5D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).